TCGA case TCGA-09-1662 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: UCSF. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/867f9563-16c9-45a8-b519-6df61ba1b6b7

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 58 years; Vital status: Dead; Days to death: 2,717 days (7.4 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 58.2 years (21,246 days); Year of diagnosis: 2001; Method of diagnosis: Surgical Resection; FIGO stage: Stage IV; Tumor grade: G3; Prior treatment: No.
   Pathology details: Lymphatic invasion present: Yes; Residual tumor measurement: 1-10 mm; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 15 days; Days to treatment end: 15 days; Number of cycles: 1; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 15 days; Days to treatment end: 15 days; Number of cycles: 1; Treatment dose: 175 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Days to treatment start: 32 days; Days to treatment end: 141 days; Number of cycles: 6; Treatment dose: 75 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine Hydrochloride; Treatment intent type: Adjuvant; Days to treatment start: 32 days; Days to treatment end: 141 days; Number of cycles: 6; Treatment dose: 600 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 1,128 days (3.1 years); Days to treatment end: 1,233 days (3.4 years); Number of cycles: 6; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Initial disease status: Recurrent Disease; Days to treatment start: 1,128 days (3.1 years); Days to treatment end: 1,233 days (3.4 years); Number of cycles: 6; Treatment dose: 60 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 1,590 days (4.4 years); Days to treatment end: 1,732 days (4.7 years); Number of cycles: 9; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Initial disease status: Recurrent Disease; Days to treatment start: 1,590 days (4.4 years); Days to treatment end: 1,732 days (4.7 years); Number of cycles: 9; Treatment dose: 60 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Anastrozole; Initial disease status: Recurrent Disease; Days to treatment start: 1,926 days (5.3 years); Treatment dose: 1 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 1,947 days (5.3 years); Days to treatment end: 1,968 days (5.4 years); Number of cycles: 2; Treatment dose: 390 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Initial disease status: Recurrent Disease; Days to treatment start: 1,947 days (5.3 years); Days to treatment end: 1,968 days (5.4 years); Number of cycles: 2; Treatment dose: 98 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Initial disease status: Recurrent Disease; Days to treatment start: 1,989 days (5.4 years); Days to treatment end: 2,052 days (5.6 years); Number of cycles: 6; Treatment dose: 100 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 2,073 days (5.7 years); Days to treatment end: 2,399 days (6.6 years); Number of cycles: 12; Treatment dose: 40 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Progressive Disease; Days to treatment start: 2,426 days (6.6 years); Days to treatment end: 2,650 days (7.3 years); Number of cycles: 9; Treatment dose: 2 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Progressive Disease; Days to treatment start: 2,457 days (6.7 years); Days to treatment end: 2,461 days (6.7 years); Number of cycles: 9; Treatment dose: 3 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Progressive Disease; Days to treatment start: 2,482 days (6.8 years); Days to treatment end: 2,602 days (7.1 years); Number of cycles: 9; Treatment dose: 4 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 2,503 days (6.9 years); Days to treatment end: 2,517 days (6.9 years); Treatment dose: 10 mg/kg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 2,530 days (6.9 years); Days to treatment end: 2,537 days (6.9 years); Number of cycles: 2; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 2,566 days (7.0 years); Days to treatment end: 2,650 days (7.3 years); Treatment dose: 10 mg/kg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Progressive Disease; Days to treatment start: 2,608 days (7.1 years); Days to treatment end: 2,623 days (7.2 years); Number of cycles: 9; Treatment dose: 2 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Progressive Disease; Days to treatment start: 2,623 days (7.2 years); Days to treatment end: 2,650 days (7.3 years); Number of cycles: 9; Treatment dose: 4 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Progressive Disease; Days to treatment start: 2,684 days (7.3 years); Days to treatment end: 2,697 days (7.4 years); Number of cycles: 3; Treatment dose: 47 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 2,684 days (7.3 years); Days to treatment end: 2,697 days (7.4 years); Number of cycles: 3; Treatment dose: 954 mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 61.0 years (22,292 days); Days to diagnosis: 1,046 days (2.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 1,081 days (3.0 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 1,046 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 1,046 days (2.9 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 2,717 days (7.4 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Distant; Evidence of progression type: Convincing Image Source; Timepoint: Post Initial Treatment.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-09-1662-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 0.7; Shortest dimension: 0.5.
  Slide TCGA-09-1662-01A-01-BS1: Section location: Bottom; Percent tumor cells: 87; Percent tumor nuclei: 95; Percent normal cells: 10; Percent necrosis: 3; Percent stromal cells: 0.
  Slide TCGA-09-1662-01A-01-TS1: Section location: Top; Percent tumor cells: 87; Percent tumor nuclei: 85; Percent normal cells: 8; Percent necrosis: 5; Percent stromal cells: 0.
- Sample TCGA-09-1662-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Anatomic organ subdivision: Left; Method initial path diagnosis: Tumor resection; Lymphovascular invasion indicator: Yes.
- Drug treatment 1: Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: Doxil.
- Drug treatment 4: Pharmaceutical therapy drug name: Taxotere.
- Drug treatment 5: Pharmaceutical therapy drug name: Toptecan; Therapy regimen: Progression.
- Drug treatment 10: Pharmaceutical therapy drug name: Gemzar; Therapy regimen: Progression.
- Drug treatment 16: Pharmaceutical therapy drug name: Avastin; Therapy regimen: Progression.
- Drug treatment 17: Pharmaceutical therapy drug name: Armidex.
- Drug treatment 20: Pharmaceutical therapy drug name: Taxol.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,717 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 2,717 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,046 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-09-1662-01): tumor purity 0.85, ploidy 1.93, whole-genome doublings 0 (call status: legacy_call).
